Somatic mutation profile of tumor specimen TCGA-G4-6315-01A (aliquot TCGA-G4-6315-01A-11D-1719-10) from TCGA case TCGA-G4-6315, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Descending colon; AJCC pathologic stage: Stage IV; Age at diagnosis: 66.2 years (24,174 days).
Specimen TCGA-G4-6315-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c74721bc-fcee-4b2f-9d7d-85ad54ba1282.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G4-6315-10A (Blood Derived Normal), aliquot TCGA-G4-6315-10A-01D-1720-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cc80c6d1-6cc4-493a-938a-2786c9619de9

The open-access MAF lists 161 somatic variants for this specimen: 119 protein-altering or splice-affecting, 40 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 99, Silent 40, Nonsense Mutation 9, Frame Shift Del 4, Frame Shift Ins 4, Intron 2, Splice Region 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.646C>T p.R216* | Nonsense Mutation (SNP) | VAF 61/196 reads (31%) | hotspot (GDC flag); catalogued as rs62619935, CM992133, COSV57320867; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.4057G>T p.E1353* | Nonsense Mutation (SNP) | VAF 40/148 reads (27%) | hotspot (GDC flag); catalogued as rs1114167568, CD972008, CM130060, COSV57321750, COSV57332693; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KCNMA1 | c.2026dup p.Y676Lfs*7 | Frame Shift Ins (INS) | VAF 11/100 reads (11%) | catalogued as rs762705295; ClinVar: pathogenic; called by mutect2, varscan2
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 90/234 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 64/162 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- WWOX | c.160C>T p.R54* | Nonsense Mutation (SNP) | VAF 41/163 reads (25%) | catalogued as rs587777248, CM141493, COSV63435802; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AASS | c.1076C>T p.T359I | Missense Mutation (SNP) | VAF 14/177 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.031); catalogued as COSV100741901; called by muse, mutect2
- ABAT | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs903118661, COSV51620386; called by muse, mutect2, varscan2
- AFP | c.404C>T p.S135L | Missense Mutation (SNP) | VAF 37/188 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.494); catalogued as rs754667512, COSV56927239; called by muse, mutect2, varscan2
- AIFM1 | c.794G>T p.R265I | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV54857904; called by muse, mutect2, varscan2
- ALCAM | c.1100T>C p.M367T | Missense Mutation (SNP) | VAF 28/215 reads (13%) | SIFT tolerated (0.93); PolyPhen benign (0.237); catalogued as COSV60255328; called by muse, mutect2, varscan2
- AP1S3 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 51/199 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1024786155, COSV57513150; called by muse, mutect2, varscan2
- ARHGAP20 | c.1122C>A p.D374E | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.988); catalogued as COSV99505495; called by muse, mutect2, varscan2
- ARSF | c.1121G>C p.G374A | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.38); catalogued as COSV63839015, COSV63841155; called by muse, varscan2
- BFSP2 | c.74C>A p.A25E | Missense Mutation (SNP) | VAF 19/146 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.076); catalogued as COSV56592247; called by muse, mutect2, varscan2
- BRWD3 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 141/220 reads (64%) | SIFT tolerated (0.08); PolyPhen benign (0.186); catalogued as COSV64753921; called by muse, mutect2, varscan2
- CACNA1B | c.5455G>A p.A1819T | Missense Mutation (SNP) | VAF 29/165 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.79); catalogued as rs200122209; called by muse, mutect2, varscan2
- CAPN3 | c.281C>A p.P94H | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as COSV58821911, COSV58826597; called by muse, mutect2, varscan2
- CARD10 | c.2536C>T p.R846W | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs755453339, COSV52656302; called by muse, mutect2, varscan2
- CASS4 | c.1180G>C p.E394Q | Missense Mutation (SNP) | VAF 53/269 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.782); catalogued as COSV64388571; called by muse, mutect2, varscan2
- CCDC34 | c.287T>A p.V96E | Missense Mutation (SNP) | VAF 139/335 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV58727173; called by muse, mutect2, varscan2
- CCDC39 | c.1523T>G p.L508R | Missense Mutation (SNP) | VAF 27/208 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56494262; called by muse, mutect2, varscan2
- CCDC39 | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 55/369 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV56486522; called by muse, mutect2, varscan2
- CFAP47 | c.4953_4954insG p.F1652Vfs*4 | Frame Shift Ins (INS) | VAF 55/208 reads (26%) | catalogued as COSV57976806; called by mutect2, pindel, varscan2
- CFAP53 | c.1435G>A p.A479T | Missense Mutation (SNP) | VAF 238/531 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV68352913; called by muse, mutect2, varscan2
- CFHR3 | c.440C>G p.S147* | Nonsense Mutation (SNP) | VAF 55/251 reads (22%) | catalogued as COSV66403336; called by muse, mutect2, varscan2
- CHST6 | c.865G>A p.A289T | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.017); catalogued as COSV60001096; called by muse, mutect2, varscan2
- CIDEA | c.503G>T p.G168V | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as COSV57600834; called by muse, mutect2, varscan2
- COL11A1 | c.4557A>G p.G1519= | Splice Region (SNP) | VAF 33/103 reads (32%) | catalogued as COSV62198606; called by muse, mutect2, varscan2
- COL4A2 | c.5G>A p.G2E | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.025); catalogued as COSV64634439; called by muse, mutect2, varscan2
- CRNN | c.62C>T p.T21M | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.085); catalogued as rs201339909; called by muse, mutect2, varscan2
- CSMD1 | c.7889C>A p.P2630Q (on ENST00000520002; = p.P2629Q on NM_033225.6) | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV59386908; called by muse, mutect2, varscan2
- CTNNA2 | c.1657A>T p.I553F | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as COSV58182838; called by muse, mutect2, varscan2
- CX3CL1 | c.1154G>A p.R385Q | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.707); catalogued as rs199662906, COSV50057070; called by muse, mutect2, varscan2
- DOCK6 | c.3455A>G p.Y1152C | Missense Mutation (SNP) | VAF 23/204 reads (11%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.95); catalogued as rs765117837, COSV53922950; called by muse, mutect2, varscan2
- DST | c.752A>G p.Y251C | Missense Mutation (SNP) | VAF 33/225 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56815955; called by muse, mutect2, varscan2
- EEF1A2 | c.895C>G p.L299V | Missense Mutation (SNP) | VAF 17/228 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.096); catalogued as COSV99420036; called by muse, mutect2
- EIF3D | c.1369G>A p.V457M | Missense Mutation (SNP) | VAF 24/157 reads (15%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.553); catalogued as rs774999741, COSV53400657; called by muse, mutect2, varscan2
- EIF4E1B | c.601G>A p.V201M | Missense Mutation (SNP) | VAF 46/150 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1048115730, COSV53779372; called by muse, mutect2, varscan2
- F13B | c.1694C>G p.A565G | Missense Mutation (SNP) | VAF 24/157 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.257); catalogued as COSV66375780; called by muse, mutect2, varscan2
- FAAH2 | c.1321G>T p.D441Y | Missense Mutation (SNP) | VAF 96/164 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV66508506, COSV66512115; called by muse, mutect2, varscan2
- FBXW12 | c.202T>C p.F68L | Missense Mutation (SNP) | VAF 48/181 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as COSV99601836; called by muse, mutect2, varscan2
- FCRL6 | c.101C>A p.A34D | Missense Mutation (SNP) | VAF 41/230 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.494); catalogued as COSV58942803; called by muse, mutect2, varscan2
- FHOD3 | c.830C>A p.P277Q | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV99943194; called by muse, mutect2, varscan2
- GNPAT | c.112A>G p.I38V | Missense Mutation (SNP) | VAF 47/149 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV64154395; called by muse, mutect2, varscan2
- GPRASP1 | c.2444T>A p.F815Y | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.968); catalogued as COSV64356531; called by muse, mutect2, varscan2
- HECW1 | c.1945G>A p.D649N | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.014); catalogued as rs769155947, COSV67840542; called by muse, mutect2, varscan2
- HECW1 | c.4562G>A p.R1521H | Missense Mutation (SNP) | VAF 46/185 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.082); catalogued as rs756422420, COSV67837695; called by muse, mutect2, varscan2
- HESX1 | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 165/568 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs766234350, CM1110145, COSV55843341, COSV55843561; called by muse, mutect2, varscan2
- HIVEP3 | c.1462C>T p.R488W | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs750482011, COSV56024196; called by muse, mutect2, varscan2
- HJV | c.116T>C p.I39T | Missense Mutation (SNP) | VAF 62/159 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1347415302, COSV60953222; called by muse, mutect2, varscan2
- HOGA1 | c.664G>T p.G222* | Nonsense Mutation (SNP) | VAF 36/188 reads (19%) | catalogued as COSV65706761; called by muse, mutect2, varscan2
- HOXD4 | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV100106913, COSV60459563; called by muse, mutect2, varscan2
- IGF2BP3 | c.505C>T p.R169* | Nonsense Mutation (SNP) | VAF 30/145 reads (21%) | catalogued as COSV51687998; called by muse, mutect2, varscan2
- IGSF9B | c.2500G>A p.V834M | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs771150072, COSV58068494; called by muse, mutect2, varscan2
- IRF4 | c.604G>A p.G202S | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs143144957; called by muse, mutect2, varscan2
- KCNJ15 | c.638C>G p.S213C | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.935); catalogued as COSV60812048; called by muse, mutect2, varscan2
- KCNS3 | c.247T>G p.Y83D | Missense Mutation (SNP) | VAF 39/265 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100411484; called by muse, mutect2, varscan2
- KRTAP27-1 | c.494C>G p.S165C | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV67001694; called by muse, mutect2, varscan2
- LIFR | c.1528C>T p.R510C | Missense Mutation (SNP) | VAF 78/300 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1360273931, COSV54690495; called by muse, mutect2, varscan2
- LIPI | c.1040dup p.L347Ffs*23 | Frame Shift Ins (INS) | VAF 40/117 reads (34%) | catalogued as rs773551412; called by mutect2, pindel, varscan2
- LRCH2 | c.1810G>T p.G604C | Missense Mutation (SNP) | VAF 65/105 reads (62%) | SIFT tolerated (0.06); PolyPhen benign (0.089); catalogued as COSV57760599; called by muse, mutect2, varscan2
- MAGI1 | c.3865C>T p.P1289S | Missense Mutation (SNP) | VAF 138/380 reads (36%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV58345642; called by muse, mutect2, varscan2
- MAGI1 | c.2161C>T p.R721* | Nonsense Mutation (SNP) | VAF 37/125 reads (30%) | catalogued as COSV58345651; called by muse, mutect2, varscan2
- MFSD13A | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.46); catalogued as rs770923282, COSV53269440; called by muse, mutect2, varscan2
- MOB3A | c.244G>A p.G82S | Missense Mutation (SNP) | VAF 54/208 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs772099363, COSV63865559; called by muse, mutect2, varscan2
- MYO1G | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 68/303 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764134145, COSV51857197; called by muse, mutect2, varscan2
- NPAP1 | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.991); catalogued as COSV61511590; called by muse, mutect2, varscan2
- NTRK2 | c.511A>C p.T171P | Missense Mutation (SNP) | VAF 29/269 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.327); catalogued as COSV52883598; called by muse, mutect2, varscan2
- NWD1 | c.3815C>T p.T1272M | Missense Mutation (SNP) | VAF 55/155 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.828); catalogued as rs758051323, COSV60339292; called by muse, mutect2, varscan2
- OBSCN | c.5491G>A p.E1831K | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as rs771065000, COSV99472345; called by muse, mutect2, varscan2
- ODF2L | c.1820A>T p.K607I (on ENST00000317336; = p.K591I on NM_020729.3) | Missense Mutation (SNP) | VAF 290/906 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54018822; called by muse, mutect2, varscan2
- OR10P1 | c.788C>T p.P263L | Missense Mutation (SNP) | VAF 63/183 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.176); catalogued as rs536972157, COSV59008496; called by muse, mutect2, varscan2
- OR51Q1 | c.679A>G p.I227V | Missense Mutation (SNP) | VAF 73/408 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV56180631; called by muse, mutect2
- OTUD7A | c.1711_1713del p.K571del (on ENST00000307050 / NM_001382637.1; = p.K564del on NM_130901.3) | In Frame Del (DEL) | VAF 5/46 reads (11%) | catalogued as rs756129773; called by pindel, varscan2
- PAX1 | c.686C>T p.A229V | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.223); catalogued as rs767391855, COSV68272006, COSV68272053; called by muse, mutect2
- PCDHA13 | c.2357C>A p.T786K | Missense Mutation (SNP) | VAF 113/370 reads (31%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0); catalogued as COSV56547853; called by muse, mutect2, varscan2
- PCDHGA6 | c.2128G>A p.V710M | Missense Mutation (SNP) | VAF 58/399 reads (15%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.185); catalogued as COSV54038146; called by muse, mutect2, varscan2
- PCLO | c.15013A>T p.T5005S | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.421); catalogued as COSV61668163; called by muse, mutect2, varscan2
- PCLO | c.11198C>A p.S3733Y | Missense Mutation (SNP) | VAF 141/532 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as COSV61622891, COSV61668169; called by muse, mutect2, varscan2
- PHF1 | c.100G>A p.G34S | Missense Mutation (SNP) | VAF 56/188 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65703432; called by muse, mutect2, varscan2
- PHRF1 | c.1204C>A p.P402T | Missense Mutation (SNP) | VAF 27/163 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52763090; called by muse, mutect2, varscan2
- PIK3R2 | c.415+1G>A p.X139_splice | Splice Site (SNP) | VAF 62/211 reads (29%) | catalogued as COSV55848558; called by muse, mutect2, varscan2
- PKP4 | c.3322C>T p.R1108W | Missense Mutation (SNP) | VAF 131/514 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.117); catalogued as rs1301343976, COSV61580512; called by muse, mutect2, varscan2
- PLCG1 | c.3733C>T p.R1245W (on ENST00000373271 / NM_182811.2; = p.R1246W on NM_002660.3) | Missense Mutation (SNP) | VAF 23/139 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs1381565968, COSV99719336; called by muse, mutect2, varscan2
- PLK1 | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 63/217 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55621195; called by muse, mutect2, varscan2
- PNPLA8 | c.2206A>G p.K736E | Missense Mutation (SNP) | VAF 18/248 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.034); catalogued as COSV99993848; called by muse, mutect2
- POTEA | c.1248C>A p.N416K (on ENST00000519951 / NM_001005365.2; = p.N370K on NM_001002920.1) | Missense Mutation (SNP) | VAF 77/195 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.217); catalogued as rs746892979; called by muse, mutect2, varscan2
- PRLR | c.860G>A p.G287D | Missense Mutation (SNP) | VAF 41/136 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375251112; called by muse, mutect2, varscan2
- PSG4 | c.259C>G p.Q87E | Missense Mutation (SNP) | VAF 38/287 reads (13%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV54941298; called by muse, mutect2, varscan2
- RGS7 | c.388G>A p.V130I | Missense Mutation (SNP) | VAF 90/287 reads (31%) | SIFT tolerated (0.77); PolyPhen benign (0.006); catalogued as rs770058894, COSV58561898; called by muse, mutect2, varscan2
- RO60 | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 109/296 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.422); catalogued as rs763830792, COSV66474115; called by muse, mutect2, varscan2
- RSPH6A | c.1318C>T p.R440W | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs199908592; called by muse, mutect2, varscan2
- RYR3 | c.8156C>T p.P2719L (on ENST00000389232; = p.P2720L on NM_001036.6) | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.135); catalogued as COSV66810991; called by muse, mutect2, varscan2
- SF3B1 | c.596G>A p.R199H | Missense Mutation (SNP) | VAF 111/347 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV59228246; called by muse, mutect2, varscan2
- SIGLEC1 | c.868C>A p.L290M | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52473454; called by muse, mutect2, varscan2
- SLA | c.232G>T p.A78S (on ENST00000338087 / NM_001045556.3; = p.A118S on NM_006748.4) | Missense Mutation (SNP) | VAF 48/175 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.574); catalogued as COSV55095284; called by muse, mutect2, varscan2
- SLC13A1 | c.874G>T p.A292S | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT tolerated (0.7); PolyPhen benign (0.134); catalogued as COSV52017152; called by muse, mutect2, varscan2
- SLC33A1 | c.1565T>G p.F522C | Missense Mutation (SNP) | VAF 236/838 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.111); catalogued as COSV63947768; called by muse, mutect2, varscan2
- SNAP91 | c.736C>T p.R246* | Nonsense Mutation (SNP) | VAF 86/270 reads (32%) | catalogued as COSV52123632; called by muse, mutect2, varscan2
- SOX17 | c.200G>A p.R67H | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV52025867; called by muse, mutect2, varscan2
- SPEF2 | c.3154G>T p.D1052Y | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV100606041, COSV61553925; called by muse, mutect2, varscan2
- TEK | c.2059G>T p.V687L | Missense Mutation (SNP) | VAF 69/276 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.253); catalogued as COSV66231569; called by muse, mutect2, varscan2
- TMEM200A | c.614T>A p.L205* | Nonsense Mutation (SNP) | VAF 48/153 reads (31%) | catalogued as COSV51660001; called by muse, mutect2, varscan2
- TRIL | c.224C>T p.T75M | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100538999; called by muse, mutect2, varscan2
- TRIM32 | c.1923G>C p.K641N | Missense Mutation (SNP) | VAF 61/208 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57818874; called by muse, mutect2, varscan2
- TRPC7 | c.1136G>A p.R379Q | Missense Mutation (SNP) | VAF 44/138 reads (32%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs776675990, COSV61464386; called by muse, mutect2, varscan2
- UNC13C | c.4531G>A p.D1511N | Missense Mutation (SNP) | VAF 28/220 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99523473; called by muse, mutect2, varscan2
- UTP20 | c.56T>G p.F19C | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777483339, COSV55385759; called by muse, mutect2, varscan2
- WDR47 | c.2438G>A p.R813H (on ENST00000369962 / NM_001142551.2; = p.R814H on NM_014969.5) | Missense Mutation (SNP) | VAF 56/166 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs371074191; called by muse, mutect2, varscan2
- WNT5A | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 81/264 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.921); catalogued as rs181787192; called by muse, mutect2, varscan2
- ZFYVE28 | c.530C>T p.S177L | Missense Mutation (SNP) | VAF 62/175 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs781628886, COSV52111984; called by muse, mutect2, varscan2
- ZNF587 | c.586G>C p.D196H | Missense Mutation (SNP) | VAF 174/1641 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.034); catalogued as COSV100299697; called by muse, mutect2, varscan2
- CRTC1 | c.732del p.S245Pfs*5 | Frame Shift Del (DEL) | VAF 33/209 reads (16%) | called by mutect2, pindel, varscan2
- CUBN | c.2715del p.L906Ffs*6 | Frame Shift Del (DEL) | VAF 77/280 reads (28%) | called by mutect2, pindel, varscan2
- FTL | c.423_427dup p.K143Ifs*9 | Frame Shift Ins (INS) | VAF 19/63 reads (30%) | called by mutect2, pindel, varscan2
- IGKV3-11 | c.311C>A p.A104E | Missense Mutation (SNP) | VAF 337/1208 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- MAP9 | c.1779del p.D594Ifs*82 | Frame Shift Del (DEL) | VAF 38/288 reads (13%) | called by mutect2, pindel, varscan2
- PRKDC | c.12295del p.S4099Qfs*6 | Frame Shift Del (DEL) | VAF 66/299 reads (22%) | called by mutect2, pindel, varscan2
- ACKR1 | c.447C>T p.C149= | Silent (SNP) | VAF 21/122 reads (17%) | catalogued as COSV63673536, COSV63674678; called by muse, mutect2, varscan2
- ADAMTS13 | c.1356G>A p.R452= | Silent (SNP) | VAF 106/326 reads (33%) | catalogued as rs782424568, COSV63023257; called by muse, mutect2, varscan2
- AGAP1 | c.2457C>T p.D819= (on ENST00000304032 / NM_001037131.3; = p.D766= on NM_014914.5) | Silent (SNP) | VAF 68/249 reads (27%) | catalogued as COSV100367189; called by muse, mutect2
- AGXT | c.1029C>T p.F343= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as rs748054201, COSV56755852; called by muse, mutect2, varscan2
- ARHGAP45 | c.1959G>A p.S653= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as COSV57430595; called by muse, mutect2, varscan2
- C3orf20 | c.465C>T p.A155= | Silent (SNP) | VAF 18/202 reads (9%) | catalogued as COSV53789547; called by muse, mutect2, varscan2
- CCSER1 | c.1785C>T p.S595= | Silent (SNP) | VAF 35/230 reads (15%) | catalogued as COSV61471319; called by muse, mutect2, varscan2
- CHERP | c.399G>A p.A133= | Silent (SNP) | VAF 21/151 reads (14%) | catalogued as rs772639345, COSV52227915; called by muse, mutect2, varscan2
- COL5A1 | c.840C>T p.Y280= | Silent (SNP) | VAF 35/115 reads (30%) | catalogued as rs765347784, COSV65669270, COSV65675824; called by muse, mutect2, varscan2
- COL6A6 | c.1668T>A p.P556= | Silent (SNP) | VAF 34/111 reads (31%) | catalogued as COSV62038449; called by muse, mutect2, varscan2
- CPSF1 | c.2748C>T p.G916= | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as rs782350591, COSV58233964; called by muse, mutect2, varscan2
- CSPG5 | c.1269C>T p.C423= | Silent (SNP) | VAF 40/138 reads (29%) | catalogued as rs1218913767, COSV53132487; called by muse, mutect2, varscan2
- EXOC2 | c.2283A>G p.E761= | Silent (SNP) | VAF 22/190 reads (12%) | catalogued as COSV57872144; called by muse, mutect2, varscan2
- FAM102B | c.963T>C p.S321= | Silent (SNP) | VAF 114/405 reads (28%) | catalogued as COSV100899405; called by muse, mutect2, varscan2
- FAM43A | c.696C>T p.H232= | Silent (SNP) | VAF 21/81 reads (26%) | catalogued as COSV61673579; called by muse, mutect2, varscan2
- FBN1 | c.7851C>T p.C2617= | Silent (SNP) | VAF 24/210 reads (11%) | catalogued as rs147019323, CM098730; called by muse, mutect2, varscan2
- FSTL5 | c.2040C>T p.D680= | Silent (SNP) | VAF 23/155 reads (15%) | catalogued as rs368625257, COSV60221137; called by muse, mutect2, varscan2
- HTT | c.855A>G p.Q285= | Silent (SNP) | VAF 38/177 reads (21%) | catalogued as rs751408145, COSV61869819; called by muse, mutect2, varscan2
- IRX5 | c.1305G>T p.P435= | Silent (SNP) | VAF 19/164 reads (12%) | catalogued as COSV58060042; called by muse, mutect2, varscan2
- JARID2 | c.1188G>A p.A396= | Silent (SNP) | VAF 19/99 reads (19%) | catalogued as rs149943687; called by muse, mutect2, varscan2
- LARP1 | c.987G>C p.G329= (on ENST00000518297 / NM_033551.3; = p.G252= on NM_015315.5 and 6 other RefSeq transcripts) | Silent (SNP) | VAF 24/78 reads (31%) | catalogued as COSV60431613; called by muse, mutect2, varscan2
- MDGA1 | c.1938C>A p.P646= | Silent (SNP) | VAF 28/137 reads (20%) | catalogued as COSV51802116; called by muse, mutect2, varscan2
- MS4A7 | c.570C>A p.I190= | Silent (SNP) | VAF 73/468 reads (16%) | catalogued as COSV100279775; called by muse, mutect2, varscan2
- NRXN1 | c.855G>A p.T285= | Silent (SNP) | VAF 51/199 reads (26%) | catalogued as rs201753471, COSV58495644; called by muse, mutect2, varscan2
- OR11L1 | c.253C>T p.L85= | Silent (SNP) | VAF 17/168 reads (10%) | catalogued as rs1323632427, COSV63313477, COSV63315805; called by muse, mutect2, varscan2
- PGAP2 | c.204C>T p.G68= (on ENST00000463452 / NM_001346398.2; = p.G129= on NM_014489.4) | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as rs373314351; called by muse, mutect2, varscan2
- PRSS54 | c.1170C>T p.F390= | Silent (SNP) | VAF 47/180 reads (26%) | catalogued as COSV54687956; called by mutect2, varscan2
- PTPRC | c.2112G>A p.G704= | Silent (SNP) | VAF 8/115 reads (7%) | catalogued as COSV100723234; called by muse, mutect2
- RYR2 | c.6522C>A p.V2174= | Silent (SNP) | VAF 100/237 reads (42%) | catalogued as COSV63672440, COSV63715537; called by muse, mutect2, varscan2
- SBF2 | c.420C>A p.I140= | Silent (SNP) | VAF 18/69 reads (26%) | catalogued as rs374171105, COSV56311538; called by muse, mutect2, varscan2
- SCN3A | c.2781C>T p.N927= | Silent (SNP) | VAF 198/673 reads (29%) | catalogued as rs776326973, COSV51825236; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLITRK3 | c.1095C>A p.T365= | Silent (SNP) | VAF 65/232 reads (28%) | catalogued as COSV53847357, COSV53850850; called by muse, mutect2, varscan2
- TBX20 | c.48C>T p.N16= | Silent (SNP) | VAF 16/83 reads (19%) | catalogued as rs375102469, COSV101282443; called by muse, mutect2, varscan2
- TMPRSS12 | c.72G>A p.S24= | Silent (SNP) | VAF 19/157 reads (12%) | catalogued as rs1412879689, COSV68257352; called by muse, mutect2, varscan2
- TRMO | c.123G>A p.S41= | Silent (SNP) | VAF 42/111 reads (38%) | catalogued as rs763180676, COSV63336911; called by muse, mutect2, varscan2
- UBA1 | c.2667G>A p.K889= | Silent (SNP) | VAF 27/121 reads (22%) | catalogued as COSV60115707; called by muse, mutect2, varscan2
- USH2A | c.11814C>T p.Y3938= | Silent (SNP) | VAF 36/130 reads (28%) | catalogued as rs766042296, COSV56399354; called by muse, mutect2, varscan2
- WDR54 | c.558G>A p.T186= | Silent (SNP) | VAF 55/180 reads (31%) | catalogued as rs374027089, COSV51963913; called by muse, mutect2, varscan2
- ZNF426 | c.255C>A p.I85= | Silent (SNP) | VAF 30/118 reads (25%) | catalogued as COSV53468874, COSV53469912; called by muse, mutect2, varscan2
- ZNF530 | c.1338A>G p.Q446= | Silent (SNP) | VAF 35/116 reads (30%) | catalogued as COSV60532554; called by muse, mutect2, varscan2
- MEF2C | c.402+130G>A | Intron (SNP) | VAF 31/234 reads (13%) | catalogued as rs1371146084, COSV60925356; called by muse, mutect2, varscan2
- PML | c.1710+697C>T | Intron (SNP) | VAF 25/93 reads (27%) | catalogued as COSV51454665; called by muse, mutect2, varscan2
